Somatic mutation profile of tumor specimen TCGA-CV-A45T-01A (aliquot TCGA-CV-A45T-01A-11D-A24D-08) from TCGA case TCGA-CV-A45T, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G3; Age at diagnosis: 64.2 years (23,452 days).
Specimen TCGA-CV-A45T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08fcd4a9-3008-4056-88f2-e8a49960e4f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45T-10A (Blood Derived Normal), aliquot TCGA-CV-A45T-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/208d5ffa-6032-496f-8b07-16fc8214128e

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOL4 | c.151C>T p.H51Y (on ENST00000352371 / NM_145660.2; = p.H48Y on NM_030643.4) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV100113187; called by muse, mutect2, varscan2
- ARHGAP45 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as COSV100490630; called by muse, mutect2
- EFCAB14 | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV100905588; called by muse, mutect2
- NCS1 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969910; called by muse, mutect2
- PCDHA9 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs369746155, COSV65325902; called by muse, mutect2
- PRRC2A | c.4136A>T p.D1379V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV101051136; called by muse, mutect2
- PTPN12 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99950271; called by muse, mutect2
- RP1 | c.4247C>G p.S1416C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99607160; called by muse, mutect2
- SLC17A7 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs770176188, COSV55546565; called by muse, mutect2, varscan2
- EPDR1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- IL12RB2 | c.135C>T p.S45= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs752499097, COSV99254972; called by muse, mutect2, varscan2
- NALCN | c.4353C>T p.S1451= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1401703339, COSV99214500; called by muse, mutect2, varscan2
- AL136982.4 | n.1099C>T | RNA (SNP) | VAF 12/185 reads (6%) | catalogued as rs771266914; called by muse, mutect2
